Gene-level copy-number profile of tumor specimen TCGA-HT-A74H-01A from TCGA case TCGA-HT-A74H, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 62.6 years (22,850 days).
Specimen TCGA-HT-A74H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.54f71090-e759-4410-9825-de2fa8d0d31a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-A74H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ce4b68d-7998-4d1b-846a-f9341cc8505b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 7,022; copy number 4: 46,986; copy number 6: 5,393; copy number 8: 350; copy number 16: 24; copy number 18: 29; copy number 149: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-A74H-01A-11D-A32A-01): tumor purity 0.68, ploidy 4.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 61 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:8,461,703–9,630,997, 24 genes, copy number 16 (within-gene range 4–16): LINC01814, AC092617.1, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7, ITGB1BP1, CPSF3, IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA.
- chr2:10,911,934–11,827,409, 28 genes, copy number 18: KCNF1, RPL6P4, AC062028.1, C2orf50, SLC66A3, ROCK2, RNU6-1081P, AIDAP1, PPIAP60, AC099344.1, LINC00570, AC099344.2, AC099344.3, E2F6, GREB1, RNA5SP84, MIR4429, RNU2-13P, 5S_rRNA, RN7SL674P, NTSR2, CDK8P1, AC106875.2, LPIN1, AC106875.1, AC012456.1, AC012456.2, MIR548S.
- chr2:11,836,933–11,836,986, 1 gene, copy number 18: MIR4262.
- chr6:106,705,334–106,788,148, 1 gene, copy number 149 (within-gene range 4–149): LINC02532.
- chr6:106,784,125–107,133,170, 5 genes, copy number 149: MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr6:107,192,300–107,230,152, 2 genes, copy number 149: AL591516.1, RPS24P12.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
